Somatic mutation profile of tumor specimen TCGA-77-8139-01A (aliquot TCGA-77-8139-01A-11D-2244-08) from TCGA case TCGA-77-8139, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 72.5 years (26,464 days).
Specimen TCGA-77-8139-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6907e330-3f31-404c-b68a-b3684942e58d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-77-8139-10A (Blood Derived Normal), aliquot TCGA-77-8139-10A-01D-2244-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c39d8621-7f47-4ac1-a533-a05e50b8eb6d

The open-access MAF lists 221 somatic variants for this specimen: 172 protein-altering or splice-affecting, 47 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 148, Silent 47, Nonsense Mutation 8, Frame Shift Del 7, Splice Site 7, Intron 1, Splice Region 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACADM | c.387+1del | Frame Shift Del (DEL) | VAF 19/148 reads (13%) | catalogued as rs786204424; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- RB1 | c.2326-1del p.X776_splice | Splice Site (DEL) | VAF 36/132 reads (27%) | hotspot (GDC flag); catalogued as CD030615, CS040558, CS144110, COSV57299493, COSV57313135, COSV57324161; called by mutect2, pindel, varscan2
- TP53 | c.314G>T p.G105V | Missense Mutation (SNP) | VAF 9/41 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs587781504, COSV52708806, COSV52766179, COSV52793434; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AARS2 | c.380A>G p.H127R | Missense Mutation (SNP) | VAF 65/248 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55116843, COSV99771587; called by muse, mutect2, varscan2
- ABCA13 | c.13069T>G p.L4357V | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV101291390; called by muse, mutect2, varscan2
- ACAD11 | c.544A>G p.T182A | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.615); catalogued as COSV99392392; called by muse, mutect2, varscan2
- ACCSL | c.1550G>C p.G517A | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101122255, COSV66581227; called by muse, mutect2, varscan2
- ADAM32 | c.1649G>T p.G550V | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1486618832, COSV101165448, COSV65953381; called by muse, mutect2
- ADAMTSL1 | c.117G>A p.W39* | Nonsense Mutation (SNP) | VAF 17/72 reads (24%) | catalogued as COSV99444025, COSV99444907; called by muse, mutect2, varscan2
- ADGRB3 | c.3502C>A p.P1168T | Missense Mutation (SNP) | VAF 29/202 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV104381236, COSV53261573, COSV99487284; called by muse, mutect2, varscan2
- ADORA2A | c.636G>C p.E212D | Missense Mutation (SNP) | VAF 52/236 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV100418090; called by muse, mutect2, varscan2
- ALKBH4 | c.123+1G>T p.X41_splice | Splice Site (SNP) | VAF 10/47 reads (21%) | catalogued as COSV99479452; called by muse, mutect2, varscan2
- ALKBH4 | c.123G>T p.A41= | Splice Region (SNP) | VAF 10/48 reads (21%) | catalogued as COSV99479453; called by muse, mutect2, varscan2
- ALPK2 | c.2522A>T p.E841V | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100864599; called by muse, mutect2
- AMPD3 | c.533C>A p.S178Y (on ENST00000396553 / NM_001025389.2; = p.S187Y on NM_000480.3) | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV101158214; called by muse, mutect2, varscan2
- ANKEF1 | c.626G>A p.G209D | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV101001054; called by muse, mutect2, varscan2
- AP3B1 | c.92C>T p.S31L | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV54877546; called by muse, mutect2
- ARHGAP39 | c.3046C>A p.R1016S (on ENST00000276826 / NM_001308208.2; = p.R1047S on NM_025251.2) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.629); catalogued as COSV99431874; called by muse, mutect2, varscan2
- ASIC1 | c.793G>A p.V265M | Missense Mutation (SNP) | VAF 25/241 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs369876465; called by muse, mutect2
- ASIC5 | c.281C>A p.T94K | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV101539779; called by muse, mutect2, varscan2
- AXDND1 | c.2715+2T>C p.X905_splice | Splice Site (SNP) | VAF 9/44 reads (20%) | catalogued as COSV100858547; called by muse, mutect2, varscan2
- BDKRB2 | c.127G>C p.A43P | Missense Mutation (SNP) | VAF 79/296 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100021268, COSV100021346; called by muse, mutect2, varscan2
- BIRC6 | c.9934G>A p.V3312I | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.29); catalogued as COSV101428513; called by muse, mutect2
- BTBD7 | c.1586A>G p.N529S | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV100598048; called by muse, mutect2, varscan2
- C20orf194 | c.2332A>G p.M778V | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99331183; called by muse, mutect2, varscan2
- CALCA | c.227G>A p.S76N | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs1555026078, COSV100524071, COSV59028881; called by muse, mutect2, varscan2
- CARD6 | c.1846G>T p.G616W | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99621055; called by muse, mutect2, varscan2
- CCDC141 | c.2546T>A p.V849D | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as COSV99837175; called by muse, mutect2, varscan2
- CCDC141 | c.2545G>A p.V849I | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV99837178; called by muse, mutect2, varscan2
- CCDC83 | c.791C>A p.P264H | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs747360405, COSV99721862; called by muse, mutect2, varscan2
- CDH20 | c.1294G>T p.D432Y | Missense Mutation (SNP) | VAF 50/174 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV99406059; called by muse, mutect2, varscan2
- CDH7 | c.1119G>T p.E373D | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100542886; called by muse, mutect2, varscan2
- CDX4 | c.319G>T p.A107S | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.86); PolyPhen benign (0.015); catalogued as COSV100999145; called by muse, mutect2, varscan2
- CEACAM5 | c.1226T>G p.L409R | Missense Mutation (SNP) | VAF 44/232 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs782016288, COSV99704072; called by muse, mutect2, varscan2
- CHRNA6 | c.747C>G p.I249M | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV99373322; called by muse, mutect2, varscan2
- CNTN5 | c.1084G>T p.D362Y | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV99679418; called by muse, mutect2, varscan2
- COL20A1 | c.3456G>C p.R1152S | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs372675396, COSV58923176; called by muse, mutect2, varscan2
- COL25A1 | c.1013G>C p.G338A | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV101211588; called by muse, mutect2
- COL4A2 | c.1046C>A p.P349H | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as COSV100847427, COSV64634591; called by muse, mutect2, varscan2
- CRX | c.807C>G p.F269L | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as rs1309761683, COSV99704602; called by muse, mutect2
- CSMD3 | c.4583G>A p.C1528Y (on ENST00000297405 / NM_001363185.1; = p.C1424Y on NM_052900.3) | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52313763, COSV99841754; called by muse, mutect2
- CST2 | c.23T>C p.L8P | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100491273; called by muse, varscan2
- CSTF3 | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 7/182 reads (4%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.058); catalogued as rs1258117306; called by muse, mutect2
- CTNND2 | c.1928G>T p.R643M | Missense Mutation (SNP) | VAF 123/409 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100479315; called by muse, mutect2, varscan2
- CUX2 | c.3658A>G p.R1220G | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV99920272; called by muse, mutect2, varscan2
- CYP8B1 | c.760T>A p.W254R | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100296231; called by muse, mutect2, varscan2
- DCAF8 | c.1070G>T p.R357M | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100470680; called by mutect2, varscan2
- DKK2 | c.350G>T p.C117F | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1345743374, COSV53393484; called by muse, mutect2, varscan2
- DNAAF2 | c.608C>A p.T203K | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.098); catalogued as rs1344533305, COSV100024210; called by muse, mutect2, varscan2
- DOCK3 | c.4079A>G p.Y1360C | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99813829; called by muse, mutect2, varscan2
- ENDOG | c.653T>C p.I218T | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100778240; called by muse, mutect2, varscan2
- ENKUR | c.592C>G p.Q198E | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.013); catalogued as COSV100482194; called by muse, mutect2, varscan2
- ERBB4 | c.2793T>A p.D931E | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.154); catalogued as COSV100726614; called by muse, mutect2, varscan2
- ETHE1 | c.661G>C p.E221Q | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.175); catalogued as COSV99415845; called by muse, mutect2, varscan2
- EXD3 | c.2119G>T p.A707S | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100573842; called by muse, mutect2, varscan2
- FAT3 | c.8622G>C p.W2874C | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53104068, COSV53177219; called by mutect2, varscan2
- FIGNL1 | c.1805C>T p.A602V | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs747409875, COSV100794935; called by muse, mutect2, varscan2
- GALR1 | c.887C>A p.S296Y | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100231954, COSV100231983; called by muse, mutect2, varscan2
- GFRAL | c.629G>A p.C210Y | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1035211860, COSV100475598, COSV61230520; called by muse, mutect2, varscan2
- GGT5 | c.230G>T p.C77F | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99571748; called by muse, mutect2, varscan2
- GOLGB1 | c.8831C>A p.S2944Y | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.894); catalogued as COSV100511284; called by muse, mutect2, varscan2
- GPR15 | c.954C>A p.C318* | Nonsense Mutation (SNP) | VAF 22/125 reads (18%) | catalogued as COSV52520574, COSV99423893; called by muse, mutect2, varscan2
- GRIN2A | c.2960C>G p.T987S | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.989); catalogued as COSV100410507; called by muse, mutect2, varscan2
- H1-1 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV55118900; called by muse, mutect2, varscan2
- HDAC4 | c.3098G>T p.R1033L | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as COSV100613942; called by muse, mutect2, varscan2
- HERC1 | c.1261G>A p.D421N | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.826); catalogued as COSV101496753; called by muse, mutect2, varscan2
- HMCN1 | c.1227T>G p.D409E | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV99632867; called by muse, mutect2, varscan2
- HOXD12 | c.746G>T p.W249L | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101184315; called by muse, mutect2, varscan2
- HTR3B | c.328C>G p.L110V | Missense Mutation (SNP) | VAF 47/194 reads (24%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.652); catalogued as COSV99492162; called by muse, mutect2, varscan2
- IRF9 | c.59T>C p.V20A | Missense Mutation (SNP) | VAF 53/282 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV100138227; called by muse, mutect2, varscan2
- IRGC | c.341G>A p.G114E | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1312650538, COSV99746442; called by muse, mutect2, varscan2
- KCNA4 | c.1008G>T p.R336S | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV100069139; called by muse, mutect2, varscan2
- KCNB2 | c.203A>G p.N68S | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.262); catalogued as COSV101578886; called by muse, mutect2, varscan2
- KCNH7 | c.1115A>G p.E372G | Missense Mutation (SNP) | VAF 29/183 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV100036989; called by muse, mutect2, varscan2
- KCNJ9 | c.430A>G p.I144V | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs781758954, COSV100927778; called by muse, mutect2, varscan2
- KCNK3 | c.416T>C p.L139P | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100257045; called by muse, mutect2, varscan2
- KIF1A | c.3761G>C p.S1254T (on ENST00000320389 / NM_001379639.1; = p.S1246T on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.405); catalogued as COSV100241865; called by muse, mutect2, varscan2
- KRCC1 | c.239C>G p.T80R | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV100712849; called by muse, mutect2
- LRP1B | c.6123G>T p.W2041C | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101258674; called by muse, mutect2, varscan2
- LRP1B | c.5359G>A p.D1787N | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as COSV101258675, COSV67258218; called by muse, mutect2
- LRP2 | c.11417C>G p.T3806R | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.259); catalogued as COSV99789585; called by muse, mutect2, varscan2
- MAN1A1 | c.377A>G p.E126G | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.114); catalogued as COSV100870406; called by muse, mutect2, varscan2
- MAP3K12 | c.246G>C p.Q82H | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.626); catalogued as COSV57235857, COSV99913427; called by muse, mutect2, varscan2
- MINAR1 | c.1462A>G p.R488G | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1169933575, COSV100549083; called by muse, mutect2, varscan2
- MRE11 | c.1048G>T p.E350* | Nonsense Mutation (SNP) | VAF 21/115 reads (18%) | catalogued as rs781140391, COSV100119914; called by muse, mutect2, varscan2
- MROH1 | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369873355, COSV100395979; called by muse, mutect2, varscan2
- MTPAP | c.1366A>T p.N456Y | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.472); catalogued as COSV99554226; called by muse, mutect2
- MYEOV | c.517G>T p.V173F | Missense Mutation (SNP) | VAF 80/324 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.457); catalogued as COSV100456703; called by muse, mutect2, varscan2
- MYRF | c.2252C>T p.S751L (on ENST00000278836 / NM_001127392.3; = p.S742L on NM_013279.4) | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.68); PolyPhen benign (0.006); catalogued as rs769451102, COSV53888621; called by mutect2, varscan2
- NAV2 | c.4402G>A p.V1468I (on ENST00000396087 / NM_001244963.2; = p.V1445I on NM_145117.5) | Missense Mutation (SNP) | VAF 42/221 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs377126212; called by muse, mutect2, varscan2
- NEXMIF | c.4316A>G p.N1439S | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.523); catalogued as COSV99281354; called by muse, mutect2, varscan2
- NFE2L1 | c.281A>G p.Q94R | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV100671644; called by muse, mutect2, varscan2
- NINL | c.3004G>A p.E1002K | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs779687148, COSV54001337; called by muse, mutect2, varscan2
- NME8 | c.793G>A p.G265R | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV99553627; called by muse, mutect2, varscan2
- NOTCH1 | c.7630C>T p.Q2544* | Nonsense Mutation (SNP) | VAF 10/25 reads (40%) | catalogued as COSV99490144; called by muse, mutect2, varscan2
- NOTCH2 | c.5930-2A>T p.X1977_splice | Splice Site (SNP) | VAF 23/73 reads (32%) | catalogued as COSV99865703; called by muse, mutect2, varscan2
- NOTCH3 | c.5938G>A p.A1980T | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367885841; called by muse, mutect2, varscan2
- NPNT | c.453C>G p.C151W | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99975323; called by muse, mutect2, varscan2
- NVL | c.829G>C p.V277L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.144); catalogued as COSV99894825; called by muse, mutect2, varscan2
- OR10G8 | c.243G>A p.M81I | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.989); catalogued as COSV101461853; called by muse, mutect2, varscan2
- OR2T8 | c.910G>T p.G304C | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV100178378; called by muse, mutect2, varscan2
- OR4D9 | c.804C>A p.D268E | Missense Mutation (SNP) | VAF 86/436 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV100259921; called by muse, mutect2, varscan2
- OR52J3 | c.208A>T p.T70S | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.73); PolyPhen benign (0.009); catalogued as COSV100984908; called by muse, mutect2, varscan2
- OR5I1 | c.481C>T p.H161Y | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100041600; called by muse, mutect2, varscan2
- OR5K4 | c.163C>A p.L55I | Missense Mutation (SNP) | VAF 86/386 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV100721379; called by muse, mutect2, varscan2
- OR7D4 | c.405C>G p.I135M | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV100432818; called by muse, varscan2
- PACS2 | c.1694G>T p.R565L | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100330891; called by muse, mutect2, varscan2
- PAPPA | c.1346T>C p.V449A | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1421011212, COSV100074821; called by muse, mutect2, varscan2
- PCDH15 | c.3976C>G p.L1326V | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.878); catalogued as COSV100224774; called by muse, mutect2, varscan2
- PCDH17 | c.1857G>T p.E619D | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.717); catalogued as COSV100931490, COSV100931798; called by muse, mutect2, varscan2
- PCDHB8 | c.1494C>A p.H498Q | Missense Mutation (SNP) | VAF 52/623 reads (8%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.015); catalogued as rs782313982, COSV99032768, COSV99177188; called by muse, mutect2
- PCDHGA8 | c.475G>T p.D159Y | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99542951; called by muse, mutect2, varscan2
- PLXNA4 | c.2549G>C p.G850A | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV100323882, COSV100325926, COSV58164562; called by muse, mutect2
- PLXNB3 | c.638C>G p.P213R | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.761); catalogued as COSV100737689; called by muse, mutect2, varscan2
- PPP1R16B | c.1250G>C p.R417P | Missense Mutation (SNP) | VAF 42/352 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.048); catalogued as COSV100239791, COSV55378017; called by muse, mutect2, varscan2
- PRKCG | c.1072G>A p.G358R | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54732785; called by muse, mutect2, varscan2
- PROC | c.695C>A p.S232* | Nonsense Mutation (SNP) | VAF 41/252 reads (16%) | catalogued as COSV99300853; called by muse, mutect2, varscan2
- PROKR2 | c.301C>A p.L101M | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV99450486; called by muse, mutect2, varscan2
- PROX1 | c.863C>G p.A288G | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.315); catalogued as COSV99799902; called by muse, mutect2
- PTGES3L-AARSD1 | c.123-2A>T p.X41_splice (on ENST00000421990 / NM_001136042.2; = p.X23_splice on NM_025267.3) | Splice Site (SNP) | VAF 76/534 reads (14%) | catalogued as COSV100799386; called by muse, mutect2, varscan2
- RBAK | c.684A>G p.I228M | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100806724; called by muse, mutect2, varscan2
- RELN | c.4718C>A p.T1573K | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs762922371, COSV100634351, COSV59034920; called by muse, mutect2, varscan2
- SEZ6L2 | c.2105-1G>A p.X702_splice (on ENST00000308713 / NM_001114099.3; = p.X632_splice on NM_012410.4) | Splice Site (SNP) | VAF 16/55 reads (29%) | catalogued as rs1172627044, COSV100435664; called by muse, mutect2, varscan2
- SLTM | c.2063G>T p.R688L | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51054363, COSV99989323; called by muse, mutect2, varscan2
- SORCS3 | c.1159C>A p.R387S | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.101); catalogued as COSV100865227; called by muse, mutect2, varscan2
- SPATA5 | c.1613G>A p.R538Q | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs1331487466, COSV99916035; called by muse, mutect2
- SPHKAP | c.3644G>A p.S1215N | Missense Mutation (SNP) | VAF 43/172 reads (25%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.494); catalogued as COSV100764293; called by muse, mutect2, varscan2
- SPOPL | c.200G>C p.W67S | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99699631; called by muse, mutect2, varscan2
- SPRTN | c.391G>T p.G131C | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99149959; called by muse, mutect2, varscan2
- SSX1 | c.93C>G p.Y31* | Nonsense Mutation (SNP) | VAF 6/10 reads (60%) | catalogued as rs781890334, COSV100976407; called by muse, mutect2, varscan2
- STK40 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.227); catalogued as COSV100828694; called by muse, mutect2, varscan2
- STX19 | c.569A>C p.K190T | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100115669; called by muse, mutect2, varscan2
- STYXL2 | c.1768C>T p.Q590* | Nonsense Mutation (SNP) | VAF 5/38 reads (13%) | catalogued as rs760626149, COSV99609591; called by mutect2, varscan2
- SYTL3 | c.1784T>A p.V595D (on ENST00000611299 / NM_001242394.1; = p.V527D on NM_001009991.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV99792290; called by muse, mutect2, varscan2
- TAF1L | c.2672C>A p.T891K | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV54256582, COSV99645119; called by muse, mutect2, varscan2
- TAFA3 | c.41G>T p.W14L | Missense Mutation (SNP) | VAF 53/205 reads (26%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.188); catalogued as COSV100721491; called by muse, mutect2, varscan2
- TDRD5 | c.2228A>G p.N743S | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV99676762; called by muse, mutect2, varscan2
- TGM1 | c.1299-2A>G p.X433_splice | Splice Site (SNP) | VAF 18/67 reads (27%) | catalogued as COSV52863256; called by muse, mutect2, varscan2
- TMEM207 | c.106G>T p.D36Y | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV100719042; called by muse, mutect2
- TMEM229B | c.472G>T p.A158S | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.009); catalogued as COSV100664352; called by muse, mutect2, varscan2
- TMEM273 | c.155T>A p.L52Q | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100939712; called by muse, mutect2, varscan2
- TMPRSS6 | c.952G>A p.V318M | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as rs967908556, COSV60975623; called by muse, mutect2, varscan2
- TNK1 | c.1735G>A p.A579T (on ENST00000576812 / NM_001251902.2; = p.A574T on NM_003985.5) | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763689818, COSV61172809; called by muse, mutect2, varscan2
- TNN | c.711C>G p.C237W | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99512552; called by muse, mutect2, varscan2
- TNP1 | c.5C>G p.S2W | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV52696587, COSV99378586; called by muse, mutect2, varscan2
- TRIM32 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.187); catalogued as COSV100529152; called by muse, mutect2, varscan2
- TRPC5 | c.1474C>T p.R492C | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs775204265, COSV99462042; called by muse, mutect2, varscan2
- TRPM8 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.024); catalogued as rs919281308, COSV100224345; called by muse, mutect2, varscan2
- TUBG1 | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); catalogued as COSV99258830; called by muse, mutect2, varscan2
- USP10 | c.2356A>G p.T786A | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.403); catalogued as COSV99551660; called by muse, mutect2, varscan2
- UTRN | c.5360A>G p.K1787R | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100840143; called by muse, mutect2, varscan2
- WDFY3 | c.10026G>C p.E3342D | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.899); catalogued as COSV99884742; called by muse, mutect2, varscan2
- WWOX | c.1034C>T p.A345V | Missense Mutation (SNP) | VAF 35/418 reads (8%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as rs746896545, COSV68368266; called by muse, mutect2
- XIRP2 | c.9933G>T p.E3311D (on ENST00000628543; = p.E3486D on NM_152381.6) | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.433); catalogued as COSV99745550; called by muse, mutect2, varscan2
- ZC3H7A | c.1070C>G p.S357C | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV100865566; called by muse, mutect2
- ZFHX4 | c.8465A>G p.E2822G | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as COSV99265624; called by muse, mutect2, varscan2
- ZFP57 | c.971C>A p.A324E | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.6); catalogued as COSV100971929; called by muse, mutect2, varscan2
- ZFYVE26 | c.3692G>C p.C1231S | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100720634; called by muse, mutect2, varscan2
- ZNF304 | c.1927C>A p.H643N | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.139); catalogued as rs1295972239, COSV99988752; called by muse, mutect2, varscan2
- ZNF536 | c.3083C>G p.A1028G | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.313); catalogued as rs375648549, COSV100835550; called by muse, mutect2, varscan2
- ZNF583 | c.121A>T p.S41C | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.529); catalogued as COSV99382252; called by muse, mutect2, varscan2
- ZNF599 | c.1745G>A p.R582Q | Missense Mutation (SNP) | VAF 18/215 reads (8%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs200440752; called by muse, mutect2
- ZNF618 | c.469A>T p.K157* (on ENST00000374126 / NM_001318042.2; = p.K125* on NM_133374.2) | Nonsense Mutation (SNP) | VAF 17/134 reads (13%) | catalogued as COSV99930751; called by muse, mutect2, varscan2
- CAD | c.427A>G p.T143A | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT tolerated (0.76); PolyPhen benign (0.01); called by muse, mutect2
- GPC5 | c.160del p.A54Qfs*43 | Frame Shift Del (DEL) | VAF 4/25 reads (16%) | called by mutect2, pindel, varscan2
- OR4C6 | c.835_837delinsTA p.M279Yfs*2 | Frame Shift Del (DEL) | VAF 13/94 reads (14%) | called by pindel, varscan2*
- PTPRC | c.1954del p.L652Ffs*18 | Frame Shift Del (DEL) | VAF 28/106 reads (26%) | called by mutect2, varscan2
- PTPRC | c.1959del p.L654Wfs*16 | Frame Shift Del (DEL) | VAF 22/128 reads (17%) | called by mutect2*, pindel, varscan2*
- RNF14 | c.86_98del p.E29Vfs*18 | Frame Shift Del (DEL) | VAF 15/67 reads (22%) | called by mutect2, pindel, varscan2
- RNF145 | c.1178del p.P393Lfs*7 (on ENST00000424310 / NM_001199383.2; = p.P421Lfs*7 on NM_144726.2) | Frame Shift Del (DEL) | VAF 6/39 reads (15%) | called by mutect2, pindel, varscan2
- TRIM26 | c.1410C>G p.I470M | Missense Mutation (SNP) | VAF 2/10 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.403); called by muse, mutect2
- ZNF544 | c.1233_1234insA p.L412Tfs*29 | Frame Shift Ins (INS) | VAF 21/94 reads (22%) | called by mutect2, pindel*, varscan2
- ABCA6 | c.486G>A p.E162= | Silent (SNP) | VAF 11/102 reads (11%) | catalogued as rs766181076, COSV99447216; called by muse, mutect2, varscan2
- ADAMTS16 | c.2550T>A p.G850= | Silent (SNP) | VAF 18/101 reads (18%) | catalogued as COSV99942147; called by muse, mutect2, varscan2
- BSN | c.4029T>G p.T1343= | Silent (SNP) | VAF 12/108 reads (11%) | catalogued as COSV99609266; called by muse, mutect2, varscan2
- C6 | c.435C>A p.R145= | Silent (SNP) | VAF 13/194 reads (7%) | catalogued as COSV99667503; called by muse, mutect2
- CACNA1S | c.2217C>T p.A739= | Silent (SNP) | VAF 17/217 reads (8%) | catalogued as rs200379217, COSV100755205; called by muse, mutect2
- CBX4 | c.630G>T p.A210= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as rs200728320, COSV53967707, COSV53968111, COSV99490464; called by muse, mutect2
- CREBBP | c.912C>G p.V304= | Silent (SNP) | VAF 30/274 reads (11%) | catalogued as COSV99271050; called by muse, mutect2
- CSF3 | c.93C>T p.T31= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV99842185, COSV99842500; called by muse, mutect2
- DCAF12L1 | c.156G>A p.A52= | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as COSV64421849; called by muse, mutect2, varscan2
- DCAF4L2 | c.573C>G p.S191= | Silent (SNP) | VAF 34/169 reads (20%) | catalogued as COSV100151120, COSV60483769; called by muse, mutect2, varscan2
- DMXL2 | c.768G>A p.L256= | Silent (SNP) | VAF 27/159 reads (17%) | catalogued as COSV99196866; called by muse, mutect2, varscan2
- ESYT1 | c.549A>C p.R183= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as COSV99920163; called by muse, mutect2, varscan2
- GDA | c.957G>A p.L319= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as COSV99429537; called by muse, mutect2, varscan2
- HERC2 | c.13620G>A p.L4540= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as COSV55345472, COSV99875583; called by muse, mutect2, varscan2
- HTR5A | c.690C>T p.R230= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as COSV55284709; called by muse, mutect2, varscan2
- IGHG1 | c.915C>A p.V305= | Silent (SNP) | VAF 23/131 reads (18%) | catalogued as rs779141206; called by muse, mutect2, varscan2
- IGKV1D-42 | c.240C>A p.V80= | Silent (SNP) | VAF 20/76 reads (26%) | called by muse, mutect2, varscan2
- IQSEC3 | c.372C>A p.P124= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV100407443; called by muse, mutect2
- IRF4 | c.1050G>T p.L350= | Silent (SNP) | VAF 23/85 reads (27%) | catalogued as rs779044373, COSV101110919; called by muse, mutect2, varscan2
- LLGL1 | c.1347G>C p.L449= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as COSV100375554; called by muse, varscan2
- MAP3K4 | c.4263C>T p.Y1421= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV100815571; called by muse, mutect2, varscan2
- MAST1 | c.1539C>G p.L513= | Silent (SNP) | VAF 12/95 reads (13%) | catalogued as COSV99263388; called by muse, mutect2, varscan2
- MED1 | c.1573C>T p.L525= | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as COSV100328038; called by muse, mutect2, varscan2
- NBPF1 | c.2236C>T p.L746= | Silent (SNP) | VAF 40/590 reads (7%) | catalogued as COSV99844740; called by muse, mutect2
- NCKAP1L | c.1905A>C p.T635= | Silent (SNP) | VAF 64/151 reads (42%) | catalogued as rs1461156895, COSV99515456; called by muse, mutect2, varscan2
- NCSTN | c.2070C>T p.I690= | Silent (SNP) | VAF 22/182 reads (12%) | catalogued as COSV54184166, COSV54192099; called by muse, mutect2, varscan2
- NLRP13 | c.1362T>C p.S454= | Silent (SNP) | VAF 21/122 reads (17%) | catalogued as COSV100738384; called by muse, mutect2, varscan2
- OR10X1 | c.282C>A p.V94= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV100936689; called by muse, mutect2, varscan2
- OR5AP2 | c.445T>C p.L149= | Silent (SNP) | VAF 19/71 reads (27%) | catalogued as COSV100266349; called by muse, mutect2, varscan2
- OR8U1 | c.486C>T p.L162= | Silent (SNP) | VAF 66/456 reads (14%) | catalogued as rs535481699, COSV100164042; called by muse, mutect2, varscan2
- PAX3 | c.1080G>A p.R360= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as COSV100399613; called by muse, mutect2, varscan2
- PCDH10 | c.1023C>T p.H341= | Silent (SNP) | VAF 22/157 reads (14%) | catalogued as COSV52094921; called by muse, mutect2, varscan2
- PRAMEF20 | c.594C>T p.I198= | Silent (SNP) | VAF 41/353 reads (12%) | called by muse, mutect2, varscan2
- SCG2 | c.711T>C p.N237= | Silent (SNP) | VAF 55/232 reads (24%) | catalogued as COSV100544827; called by muse, mutect2, varscan2
- SCGN | c.354C>T p.D118= | Silent (SNP) | VAF 33/163 reads (20%) | catalogued as rs745811016, COSV100618812; called by muse, mutect2, varscan2
- SIGLEC1 | c.2196C>T p.S732= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as COSV99169816; called by muse, mutect2, varscan2
- SLC25A16 | c.939C>T p.P313= | Silent (SNP) | VAF 18/83 reads (22%) | catalogued as COSV99770187; called by muse, mutect2, varscan2
- SPEF2 | c.2676A>G p.K892= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV100608197; called by muse, mutect2, varscan2
- SULF1 | c.1308C>T p.P436= | Silent (SNP) | VAF 24/139 reads (17%) | catalogued as COSV99483809; called by muse, mutect2, varscan2
- TIFAB | c.123G>A p.G41= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as rs376343233; called by muse, mutect2, varscan2
- TRIM2 | c.1623A>G p.V541= (on ENST00000437508; = p.V568= on NM_015271.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 20/102 reads (20%) | called by muse, mutect2, varscan2
- TTN | c.28326G>A p.R9442= (on ENST00000591111; = p.R8515= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 60/238 reads (25%) | catalogued as rs1195605244, COSV100622541; called by muse, mutect2, varscan2
- UGT2A3 | c.426C>T p.N142= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as COSV99280107; called by muse, varscan2
- XIRP2 | c.360G>T p.V120= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as COSV54726717, COSV99745547; called by muse, mutect2, varscan2
- ZKSCAN3 | c.297G>T p.P99= | Silent (SNP) | VAF 34/104 reads (33%) | catalogued as COSV99357054; called by muse, mutect2, varscan2
- ZNF454 | c.153C>G p.V51= | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as COSV100194530, COSV100195199, COSV60770681; called by muse, mutect2, varscan2
- ZNF470 | c.354G>T p.P118= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as rs762279576, COSV100401327; called by muse, mutect2, varscan2
- MASP1 | c.1303+5237C>G | Intron (SNP) | VAF 11/107 reads (10%) | catalogued as COSV99962653; called by muse, mutect2, varscan2
- SNORD116-2 | n.22A>T | RNA (SNP) | VAF 47/200 reads (24%) | catalogued as rs1306941789; called by muse, mutect2, varscan2
